Gene-level copy-number profile of tumor specimen C3N-00437-03 from CPTAC case C3N-00437, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 69.8 years (25,495 days).
Specimen C3N-00437-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b3cdc3f1-40be-4794-bec2-5af9f4d70595.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00437-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/92a0d5cf-93ac-4da3-94eb-f706916824a7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 3,535; copy number 2: 30,070; copy number 3: 17,810; copy number 4: 5,457; copy number 5: 1,521.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr18:46,803,218–46,920,160, 3 genes (within-gene range 0–1): PIAS2, AC090241.1, AC090373.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,521 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,507,764–49,524,185, 3 genes, copy number 5: AC119751.5, AC119751.2, AC119751.8.
- chr5:767,382–1,386,409, 23 genes, copy number 5: BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3.
- chr8:46,028,804–145,066,685, 1,494 genes, copy number 5 (broad region; genes not listed).
- chr21:28,013,363–28,023,233, 1 gene, copy number 5: LINC00314.

Autosomal genes at a single copy (total copy number 1): 3,535. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
